Somatic mutation profile of tumor specimen MP2PRT-PASTID-TMP1-A (aliquot MP2PRT-PASTID-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PASTID, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,175 days).
Specimen MP2PRT-PASTID-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09d879a9-e7b1-484b-a593-0e8c0ff92ea2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASTID-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASTID-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c4d9dba-724e-46a0-9d78-fe7d0e5adf53

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SYNE1 | c.3005G>A p.R1002Q (on ENST00000367255 / NM_182961.4; = p.R1009Q on NM_033071.3) | Missense Mutation (SNP) | VAF 49/451 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55040351; called by muse, mutect2
- TENM3 | c.7087C>T p.R2363W | Missense Mutation (SNP) | VAF 42/342 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs757494710, COSV101305270; called by muse, mutect2, varscan2
- ZNF316 | c.2258G>C p.G753A | Missense Mutation (SNP) | VAF 58/467 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- DPP6 | c.1449G>T p.G483= (on ENST00000377770 / NM_001364500.2; = p.G421= on NM_001936.5) | Silent (SNP) | VAF 38/354 reads (11%) | catalogued as COSV59600545; called by muse, mutect2, varscan2
- HDGFL1 | c.156T>C p.S52= | Silent (SNP) | VAF 59/449 reads (13%) | called by muse, mutect2, varscan2
